Somatic mutation profile of tumor specimen MMRF_1184_1_BM_CD138pos (aliquot MMRF_1184_1_BM_CD138pos_T2_KHS5U_L15104) from MMRF case MMRF_1184, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.2 years (25,990 days).
Specimen MMRF_1184_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27e0202d-6d92-4961-8ca6-f2f03fa399a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1184_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1184_2_PB_Whole_C1_KBS5U_L05581; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2536dc5a-f08e-456a-b9f0-12854edc0ba8

The open-access MAF lists 103 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 29, Intron 17, Silent 9, 5'UTR 4, 5'Flank 4, RNA 2, Splice Site 2, Nonsense Mutation 1, 3'Flank 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 189/424 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BATF | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 129/259 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs777932710, COSV54375999; called by muse, mutect2, varscan2
- CA12 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs751146882, COSV99458598; called by muse, mutect2, varscan2
- CD151 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58990174; called by muse, mutect2, varscan2
- CES4A | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as rs1361698381; called by muse, mutect2, varscan2
- IGHV2-70 | c.296T>G p.V99G | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755372451; called by muse, varscan2
- IGHV2-70 | c.283T>A p.S95T | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs568191048; called by muse, varscan2
- IGHV2-70 | c.118A>C p.T40P | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553609563; called by muse, varscan2
- KLHL31 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 142/273 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs1447156615; called by muse, mutect2, varscan2
- LAMA5 | c.1316C>A p.T439N | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs547495598; called by muse, mutect2, varscan2
- MYO10 | c.3583C>T p.R1195C | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1283106000, COSV57022731, COSV57028426; called by muse, mutect2
- MYO9A | c.5507del p.R1836Qfs*3 | Frame Shift Del (DEL) | VAF 68/295 reads (23%) | catalogued as COSV61860603; called by mutect2, pindel, varscan2
- NLRC5 | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV52656023; called by muse, mutect2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 42/122 reads (34%) | catalogued as rs754860965; called by mutect2, varscan2
- TNNI3 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as COSV61277999; called by muse, mutect2, varscan2
- TRPV6 | c.1195C>A p.R399S | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV63893232; called by muse, mutect2, varscan2
- ZNF25 | c.1126G>T p.G376C | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs763742315; called by muse, mutect2, varscan2
- CHD8 | c.1209_1215+12del p.X403_splice (on ENST00000646647 / NM_001170629.2; = p.X124_splice on NM_020920.4) | Splice Site (DEL) | VAF 32/82 reads (39%) | called by mutect2, pindel, varscan2
- DDX60 | c.2614C>T p.L872F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNPEP | c.125T>A p.F42Y | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FAT1 | c.4472A>T p.Y1491F | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- FAT4 | c.4000G>C p.V1334L | Missense Mutation (SNP) | VAF 99/304 reads (33%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FOXE1 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- GFUS | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- IGHV2-70D | c.293A>C p.Q98P | Missense Mutation (SNP) | VAF 69/123 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, varscan2
- IGHV2-70D | c.148A>C p.T50P | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, varscan2
- INSYN2A | c.1067T>C p.V356A | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- KAT7 | c.852+1G>A p.X284_splice | Splice Site (SNP) | VAF 58/196 reads (30%) | called by muse, mutect2, varscan2
- KLHL6 | c.1682A>G p.Y561C | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- MAP3K10 | c.2798A>G p.D933G | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- METTL25 | c.503G>C p.S168T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- OR5T1 | c.218A>C p.Y73S | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PYURF | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SASH1 | c.719C>A p.S240* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- SYK | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.6487C>G p.H2163D (on ENST00000591111; = p.H2117D on NM_003319.4) | Missense Mutation (SNP) | VAF 35/65 reads (54%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF25 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- C4orf54 | c.3171C>T p.S1057= | Silent (SNP) | VAF 94/254 reads (37%) | called by muse, mutect2, varscan2
- CEBPE | c.180G>A p.V60= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as COSV52828937; called by muse, mutect2
- IGHV2-70D | c.297G>A p.V99= | Silent (SNP) | VAF 62/116 reads (53%) | called by muse, varscan2
- IGHV2-70D | c.93G>A p.V31= | Silent (SNP) | VAF 38/74 reads (51%) | called by muse, varscan2
- IGHV2-70D | c.81T>C p.G27= | Silent (SNP) | VAF 36/74 reads (49%) | called by muse, varscan2
- PPT2 | c.816C>A p.A272= | Silent (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- RANBP2 | c.4161C>T p.G1387= | Silent (SNP) | VAF 164/343 reads (48%) | catalogued as rs1474575032; ClinVar: likely benign; called by muse, mutect2, varscan2
- RP1 | c.2664T>C p.A888= | Silent (SNP) | VAF 44/64 reads (69%) | called by muse, mutect2, varscan2
- SLC17A1 | c.834T>C p.H278= | Silent (SNP) | VAF 61/134 reads (46%) | called by muse, mutect2
- ACP2 | c.640-20C>T | Intron (SNP) | VAF 4/89 reads (4%) | called by muse, mutect2
- AL138930.1 | n.115+3985T>G | Intron (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- ANAPC13 | c.*349G>A | 3'UTR (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500519 G>C | 5'Flank (SNP) | VAF 75/185 reads (41%) | called by muse, mutect2, varscan2
- ATF2 | c.*827G>T | 3'UTR (SNP) | VAF 34/78 reads (44%) | catalogued as rs192742819; called by muse, mutect2, varscan2
- ATP5F1A | c.1284+30G>C | Intron (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021421 G>T | 5'Flank (SNP) | VAF 71/163 reads (44%) | called by muse, mutect2, varscan2
- BMP6 | c.*146del | 3'UTR (DEL) | VAF 27/57 reads (47%) | called by mutect2, pindel, varscan2
- CA5B | c.*1902C>T | 3'UTR (SNP) | VAF 56/57 reads (98%) | called by muse, mutect2, varscan2
- CDC14B | c.*3082del | 3'UTR (DEL) | VAF 28/102 reads (27%) | called by mutect2, pindel, varscan2
- CLSPN | c.-97A>G | 5'UTR (SNP) | VAF 78/169 reads (46%) | called by muse, mutect2, varscan2
- COL4A2 | c.1433-660G>A | Intron (SNP) | VAF 71/157 reads (45%) | catalogued as rs761200719, COSV64626762; called by muse, mutect2, varscan2
- CSPG5 | c.*229G>C | 3'UTR (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- CTCF | c.952+49G>A | Intron (SNP) | VAF 10/29 reads (34%) | catalogued as rs370933309, COSV50482317; called by muse, mutect2, varscan2
- CTDSP1 | c.68-700C>T | Intron (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- DLGAP4 | c.*1359A>G | 3'UTR (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- DMXL1 | c.*605G>A | 3'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- DTD2 | c.*1974C>T | 3'UTR (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- EMD | chrX:154379274 C>T | 5'Flank (SNP) | VAF 100/102 reads (98%) | called by muse, mutect2, varscan2
- FAM43A | c.-706C>G | 5'UTR (SNP) | VAF 50/157 reads (32%) | called by muse, mutect2, varscan2
- GRIK1 | c.*60_*72del | 3'UTR (DEL) | VAF 23/64 reads (36%) | called by mutect2, pindel, varscan2
- HEMK1 | c.229-77G>A | Intron (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2
- HEY1 | chr8:79763926 A>T | 3'Flank (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- HHIP | c.*6277dup | 3'UTR (INS) | VAF 48/97 reads (49%) | catalogued as rs1038785014; called by mutect2, varscan2
- HOXD10 | c.*235A>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | catalogued as rs76652386, COSV50891482; called by muse, varscan2
- IFITM10 | c.*1489G>C | 3'UTR (SNP) | VAF 22/350 reads (6%) | called by muse, mutect2
- IRF4 | c.*2815A>G | 3'UTR (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
- KRT5 | c.1219-15C>T | Intron (SNP) | VAF 27/77 reads (35%) | catalogued as rs772025669; called by muse, mutect2, varscan2
- LDB2 | c.891+2644A>T | Intron (SNP) | VAF 11/303 reads (4%) | called by muse, mutect2
- LINC02692 | n.318G>A | RNA (SNP) | VAF 30/92 reads (33%) | catalogued as rs535158410; called by muse, mutect2, varscan2
- MED24 | c.-31G>A | 5'UTR (SNP) | VAF 77/278 reads (28%) | called by muse, mutect2, varscan2
- MET | c.*1467G>T | 3'UTR (SNP) | VAF 42/131 reads (32%) | called by muse, mutect2, varscan2
- METTL15 | c.*1892C>A | 3'UTR (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- MIR1471 | n.5G>A | RNA (SNP) | VAF 35/82 reads (43%) | catalogued as rs971791592; called by muse, mutect2, varscan2
- MNT | c.*2429G>A | 3'UTR (SNP) | VAF 67/289 reads (23%) | called by muse, mutect2, varscan2
- NLRC5 | c.295+83A>G | Intron (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2
- NR3C2 | c.*85A>G | 3'UTR (SNP) | VAF 123/327 reads (38%) | called by muse, mutect2, varscan2
- PAQR5 | c.*3698G>C | 3'UTR (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- PELI3 | c.*482A>G | 3'UTR (SNP) | VAF 60/119 reads (50%) | catalogued as rs1171578035; called by muse, mutect2, varscan2
- PIFO | c.*320A>G | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- PROX2 | c.1414-17A>G | Intron (SNP) | VAF 64/167 reads (38%) | called by muse, mutect2, varscan2
- RELN | c.*902C>T | 3'UTR (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- RPL7L1 | c.*1063A>G | 3'UTR (SNP) | VAF 8/46 reads (17%) | catalogued as rs878875910; called by muse, mutect2, varscan2
- RPS23 | c.164+185T>G | Intron (SNP) | VAF 77/127 reads (61%) | called by muse, varscan2
- RPS23 | c.164+109T>G | Intron (SNP) | VAF 88/154 reads (57%) | called by muse, varscan2
- RSPH3 | chr6:159000196 G>T | 5'Flank (SNP) | VAF 48/133 reads (36%) | called by muse, mutect2, varscan2
- SAV1 | c.*1135T>A | 3'UTR (SNP) | VAF 130/266 reads (49%) | catalogued as rs965089765, COSV100220752, COSV61204522; called by mutect2, varscan2
- SIAH2 | c.-12G>C | 5'UTR (SNP) | VAF 37/50 reads (74%) | called by muse, mutect2
- SOCS6 | c.*824del | 3'UTR (DEL) | VAF 6/64 reads (9%) | catalogued as COSV101205882; called by mutect2, pindel
- TENT5C | c.*3365T>G | 3'UTR (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- THOC7 | c.*197A>G | 3'UTR (SNP) | VAF 43/108 reads (40%) | called by muse, mutect2, varscan2
- THRB | c.*4355T>A | 3'UTR (SNP) | VAF 39/125 reads (31%) | called by muse, mutect2, varscan2
- TMEM237 | c.*1738C>T | 3'UTR (SNP) | VAF 23/47 reads (49%) | catalogued as rs372327100; called by muse, mutect2, varscan2
- TP53I11 | c.237+195G>T | Intron (SNP) | VAF 47/78 reads (60%) | called by muse, mutect2, varscan2
- TRAT1 | c.214+70C>T | Intron (SNP) | VAF 16/28 reads (57%) | catalogued as rs1291004852, COSV99849439; called by muse, mutect2, varscan2
- TRIML1 | c.736-28T>G | Intron (SNP) | VAF 94/178 reads (53%) | called by muse, mutect2, varscan2
- WDR24 | c.685+80A>G | Intron (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
